Somatic mutation profile of tumor specimen TCGA-FB-AAQ2-01A (aliquot TCGA-FB-AAQ2-01A-31D-A40W-08) from TCGA case TCGA-FB-AAQ2, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.0 years (29,585 days).
Specimen TCGA-FB-AAQ2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bb9f406-0159-4785-b97f-21adf21947b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAQ2-11A (Solid Tissue Normal), aliquot TCGA-FB-AAQ2-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a6907f7-f3b0-4dd1-b6c1-ea72ffdf03ec

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 29, Silent 6, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.132del p.Y44* | Frame Shift Del (DEL) | VAF 124/565 reads (22%) | catalogued as rs1131691187, CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; ClinVar: pathogenic; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 73/235 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 164/764 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99698168; called by muse, mutect2, varscan2
- ADAMTS16 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 105/470 reads (22%) | catalogued as rs749038125, COSV99939747; called by muse, mutect2, varscan2
- AFF2 | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 116/445 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53991906; called by muse, mutect2, varscan2
- ALDOB | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs201424676, COSV66398632; called by muse, mutect2, varscan2
- ANXA1 | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 213/913 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV99973767; called by muse, mutect2, varscan2
- ASTN1 | c.3395G>A p.R1132Q | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776112806, COSV100705342, COSV62504579; called by muse, mutect2, varscan2
- BMX | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 138/481 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1384281513, COSV59590759; called by muse, varscan2
- CCDC40 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 25/439 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749901313, COSV53901215, COSV53905198, COSV99481502; ClinVar: uncertain significance; called by muse, mutect2
- DNAH5 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV99444051; called by muse, mutect2, varscan2
- IRX6 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs377555554, COSV99306148; called by muse, mutect2, varscan2
- KALRN | c.21C>G p.D7E | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.621); catalogued as COSV99561805; called by muse, mutect2, varscan2
- KCNQ3 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 199/841 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749712918, COSV66463567; called by muse, mutect2, varscan2
- LDLRAD4 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs767437921, COSV100761780; called by muse, mutect2, varscan2
- LRRIQ3 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 111/635 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs534493116, COSV100598687, COSV63044305; called by muse, mutect2, varscan2
- NUP62 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 98/539 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as rs377108835; called by muse, mutect2, varscan2
- OMD | c.495A>T p.E165D | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100979006; called by muse, mutect2, varscan2
- PLA2G4D | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs770585872, COSV51819372; called by muse, varscan2
- RASA2 | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1442586864, COSV99655524; called by muse, mutect2, varscan2
- RASGRF1 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101369505; called by muse, mutect2, varscan2
- RNF152 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs776181105, COSV100454942; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.701G>A p.R234H (on ENST00000291839; = p.S240= on NM_013443.4) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | PolyPhen benign (0.067); catalogued as rs368787289; called by muse, mutect2, varscan2
- SULT2B1 | c.175C>T p.R59W (on ENST00000201586 / NM_177973.2; = p.R44W on NM_004605.2) | Missense Mutation (SNP) | VAF 132/564 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs371112055; called by muse, mutect2, varscan2
- TPO | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100219499, COSV61108896; called by muse, mutect2, varscan2
- TTC37 | c.4567C>T p.R1523C | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760555925, COSV62454446; called by muse, mutect2
- WNT2 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.37); catalogued as COSV99625641; called by muse, mutect2, varscan2
- ZC3H12C | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs764220083, COSV53710043; called by muse, mutect2, varscan2
- ZFYVE26 | c.5905G>A p.E1969K | Missense Mutation (SNP) | VAF 120/545 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100720018; called by muse, mutect2, varscan2
- ZNF385B | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); catalogued as rs1325673372, COSV100415701; called by muse, mutect2, varscan2
- IL4R | c.680_709del p.E227_G236del | In Frame Del (DEL) | VAF 46/386 reads (12%) | called by mutect2, pindel
- RBM10 | c.912del p.L304Ffs*4 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, varscan2
- CBY2 | c.699C>T p.H233= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as rs752236337, COSV100137404; called by muse, mutect2, varscan2
- CUL1 | c.84C>A p.I28= | Silent (SNP) | VAF 23/452 reads (5%) | catalogued as COSV100296358, COSV100296694; called by muse, mutect2
- GABRA6 | c.1155C>T p.S385= | Silent (SNP) | VAF 101/437 reads (23%) | catalogued as rs775737124, COSV50877479; called by muse, mutect2, varscan2
- PRKD2 | c.1794A>G p.E598= | Silent (SNP) | VAF 71/421 reads (17%) | catalogued as COSV99354025; called by muse, mutect2, varscan2
- RYR1 | c.10521G>A p.T3507= | Silent (SNP) | VAF 98/413 reads (24%) | catalogued as rs767618265, COSV62098999; called by muse, mutect2, varscan2
- SETD5 | c.2490A>G p.P830= | Silent (SNP) | VAF 215/914 reads (24%) | catalogued as COSV100200058; called by muse, mutect2, varscan2
